Gene-level copy-number profile of tumor specimen TCGA-D3-A51K-06A from TCGA case TCGA-D3-A51K, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.0 years (18,991 days).
Specimen TCGA-D3-A51K-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4b74414f-3418-49b8-8064-46a0760b231b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A51K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/597a5a2a-27ba-473d-b5e5-f270842b4d77

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 7,780; copy number 2: 39,859; copy number 3: 6,146; copy number 4: 4,186; copy number 5: 244; copy number 6: 1,460; copy number 7: 63; copy number 8: 5; copy number 9: 9; copy number 10: 32; copy number 11: 23; copy number 21: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A51K-06A-11D-A25P-01): tumor purity 0.85, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,488,963–48,771,827, 7 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2.
- chr15:38,139,595–38,226,897, 1 gene (within-gene range 0–1): AC087473.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,833 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,657,918–54,859,241, 3 genes, copy number 21: KIT, AC097494.1, LINC02358.
- chr5:58,198–1,594,620, 58 genes, copy number 5–7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3.
- chr5:2,921,496–2,967,955, 1 gene, copy number 9: AC094105.2.
- chr5:8,012,377–8,755,159, 23 genes, copy number 11: AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2.
- chr5:12,297,399–13,638,381, 10 genes, copy number 5–8: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1.
- chr5:15,500,180–15,939,795, 1 gene, copy number 6 (within-gene range 3–6): FBXL7.
- chr5:15,935,182–16,033,356, 2 genes, copy number 6: MIR887, RNA5SP178.
- chr5:18,049,232–18,049,872, 1 gene, copy number 5: RPL36AP21.
- chr5:25,187,800–25,324,386, 1 gene, copy number 9 (within-gene range 1–9): LINC02211.
- chr5:25,218,973–25,716,715, 7 genes, copy number 9 (within-gene range 1–9): AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1.
- chr5:28,213,359–28,287,807, 2 genes, copy number 6: AC093300.1, LINC02103.
- chr5:28,614,613–28,654,531, 2 genes, copy number 6 (within-gene range 3–6): AC109472.1, RNU6-909P.
- chr5:29,516,005–33,984,693, 70 genes, copy number 6 (broad region; genes not listed).
- chr5:34,373,028–34,839,278, 5 genes, copy number 5: AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2.
- chr5:35,429,064–35,429,277, 1 gene, copy number 6: U3.
- chr5:39,520,398–40,984,643, 23 genes, copy number 5: LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1.
- chr8:41,929,479–145,066,685, 1,591 genes, copy number 5–6 (broad region; genes not listed).
- chr10:109,940,104–111,989,909, 32 genes, copy number 10 (within-gene range 1–10): ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5, RPL7P35, SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1, BTBD7P2, AC021035.1, RPS6P15, AL136119.1.

Autosomal genes at a single copy (total copy number 1): 5,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
